Somatic mutation profile of tumor specimen C3N-02263-01 (aliquot CPT0188180006) from CPTAC case C3N-02263, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.2 years (25,262 days).
Specimen C3N-02263-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 743394ae-baf8-439e-b6db-3e6bc7bd31bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02263-31 (Blood Derived Normal), aliquot CPT0188840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edc256e1-cbb3-42db-b72d-9922d78627b5

The open-access MAF lists 103 somatic variants for this specimen: 70 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 20, Frame Shift Del 10, Intron 8, 3'UTR 4, Splice Region 3, Nonsense Mutation 3, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOTL2 | c.2057C>A p.S686Y | Missense Mutation (SNP) | VAF 138/459 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.58); catalogued as COSV99850747; called by muse, mutect2, varscan2
- ARHGAP28 | c.2059C>T p.Q687* (on ENST00000383472 / NM_001366230.1; = p.Q528* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as rs1339784683; called by muse, mutect2, varscan2
- ARMH3 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as COSV100228950, COSV100229014; called by muse, mutect2, varscan2
- DAPK1 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs765428113; called by muse, mutect2, varscan2
- GJA10 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV65355515; called by muse, mutect2, varscan2
- GPR179 | c.3389C>T p.S1130L (on ENST00000621958; = p.S1129L on NM_001004334.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750172664; called by muse, mutect2, varscan2
- GSR | c.468del p.I157Sfs*11 | Frame Shift Del (DEL) | VAF 87/386 reads (23%) | catalogued as COSV55323943; called by mutect2, pindel, varscan2
- GTF3C2 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as COSV53126408; called by muse, mutect2, varscan2
- HNF1B | c.906C>G p.N302K | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as CM104910; called by muse, mutect2, varscan2
- ITGA5 | c.2603A>G p.N868S | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.487); catalogued as rs756867133; called by muse, mutect2, varscan2
- KRT6B | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 219/836 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs764052533, COSV52883501; called by muse, mutect2, varscan2
- MOGS | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369937053; called by muse, mutect2, varscan2
- MROH2A | c.4007T>G p.L1336R | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); catalogued as COSV99062056; called by muse, mutect2, varscan2
- MSR1 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100027987; called by muse, mutect2, varscan2
- NUDT12 | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1190357601; called by muse, mutect2, varscan2
- OLFM1 | c.352G>C p.D118H (on ENST00000371793 / NM_001282611.2; = p.D100H on NM_006334.4) | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99424258; called by muse, varscan2
- QSOX1 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs968998313, COSV100852949; called by muse, mutect2, varscan2
- RIMBP2 | c.1774C>T p.H592Y | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.132); catalogued as rs139183976; called by muse, mutect2, varscan2
- TEX11 | c.1666del p.I556Lfs*10 (on ENST00000344304; = p.I541Lfs*10 on NM_031276.3) | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as COSV60236559; called by mutect2, pindel, varscan2
- TMEM132B | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs747888388, COSV54757309; called by muse, mutect2, varscan2
- TPTE | c.1623G>A p.M541I (on ENST00000618007 / NM_199261.4; = p.M523I on NM_199259.4) | Missense Mutation (SNP) | VAF 34/467 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs758305832; called by muse, mutect2
- ZNF254 | c.1781T>C p.V594A | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV61644784; called by muse, mutect2, varscan2
- ABL2 | c.497A>G p.N166S (on ENST00000502732 / NM_007314.4; = p.N151S on NM_005158.5) | Missense Mutation (SNP) | VAF 85/313 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ADCY3 | c.2435T>C p.L812S | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- AJM1 | c.1708A>C p.T570P | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2
- ALDH1L1 | c.931A>T p.S311C | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- APBB1 | c.164G>C p.G55A | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ARHGAP21 | c.280A>T p.N94Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ARHGEF17 | c.2370_2374del p.S790Rfs*39 | Frame Shift Del (DEL) | VAF 58/278 reads (21%) | called by mutect2, pindel, varscan2
- C12orf73 | c.27del p.Y10Tfs*2 | Frame Shift Del (DEL) | VAF 48/217 reads (22%) | called by mutect2, pindel, varscan2
- C2CD6 | c.516G>A p.Q172= | Splice Region (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2
- C2CD6 | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 156/632 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CD160 | c.538+6T>C | Splice Region (SNP) | VAF 81/324 reads (25%) | called by muse, mutect2, varscan2
- CENPV | c.229dup p.E77Gfs*6 | Frame Shift Ins (INS) | VAF 36/141 reads (26%) | called by pindel, varscan2
- COLEC11 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 103/347 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNPEP | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DYNC2I2 | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ECH1 | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA10 | c.2240T>C p.L747P | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM166A | c.732del p.E244Dfs*36 | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | called by mutect2, pindel, varscan2
- FER1L5 | c.5086G>A p.G1696R (on ENST00000623019; = p.G1669R on NM_001293083.2) | Missense Mutation (SNP) | VAF 86/368 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAB4 | c.1051_1052del p.D351Qfs*5 | Frame Shift Del (DEL) | VAF 42/206 reads (20%) | called by mutect2, pindel
- GNRH1 | c.254del p.E85Gfs*23 | Frame Shift Del (DEL) | VAF 51/249 reads (20%) | called by mutect2, pindel, varscan2
- HEMK1 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- HIF1A | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ITIH6 | c.1778T>C p.L593P | Missense Mutation (SNP) | VAF 162/415 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- KDM5A | c.4762G>T p.V1588L | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KDM5C | c.3623G>A p.W1208* | Nonsense Mutation (SNP) | VAF 93/263 reads (35%) | called by muse, mutect2, varscan2
- LPO | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- MAP11 | c.1476_1477insT p.K493* | Frame Shift Ins (INS) | VAF 43/205 reads (21%) | called by mutect2, pindel, varscan2
- NBPF12 | c.3636G>C p.E1212D | Missense Mutation (SNP) | VAF 38/538 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- NEK1 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- NMRK1 | c.38A>C p.N13T | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOS3 | c.2228G>A p.G743D | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NPIPB2 | c.105_114del p.D35Efs*31 | Frame Shift Del (DEL) | VAF 39/215 reads (18%) | called by mutect2, varscan2
- PAIP1 | c.836T>G p.L279R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA5 | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 246/632 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PRRC2A | c.4247G>A p.G1416D | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- PTPRG | c.4155G>T p.M1385I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- RORC | c.1298T>G p.L433R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAF8 | c.3395_3399del p.P1132Qfs*17 | Frame Shift Del (DEL) | VAF 30/157 reads (19%) | called by mutect2, pindel, varscan2
- SLC34A1 | c.1005A>G p.K335= | Splice Region (SNP) | VAF 255/586 reads (44%) | called by muse, mutect2, varscan2
- SLX4 | c.2876C>A p.S959Y | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SRGAP3 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 218/549 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.077); called by mutect2, varscan2
- SRSF6 | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SVIL | c.2539A>G p.N847D (on ENST00000355867 / NM_021738.3; = p.N421D on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UNK | c.1711T>C p.S571P | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VHL | c.261_273delinsGCT p.W88Lfs*68 | Frame Shift Del (DEL) | VAF 75/372 reads (20%) | called by pindel, varscan2*
- YME1L1 | c.369A>T p.L123F (on ENST00000326799 / NM_139312.3; = p.L66F on NM_014263.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ZP2 | c.1012T>G p.S338A | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- ANKRD30B | c.3942A>G p.R1314= | Silent (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- BCHE | c.372T>C p.N124= | Silent (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- BCL3 | c.321T>C p.P107= | Silent (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- C17orf98 | c.426G>A p.T142= | Silent (SNP) | VAF 67/260 reads (26%) | catalogued as rs1332277976; called by muse, mutect2, varscan2
- CCDC7 | c.2982A>C p.L994= | Silent (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- CEBPZ | c.1320T>C p.Y440= | Silent (SNP) | VAF 47/189 reads (25%) | catalogued as rs769243802; called by muse, mutect2, varscan2
- CENPF | c.3741C>G p.T1247= | Silent (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- FAM120B | c.63A>C p.V21= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- FRMD1 | c.708G>A p.E236= | Silent (SNP) | VAF 51/254 reads (20%) | catalogued as rs772486751; called by muse, mutect2, varscan2
- FRMPD2 | c.1326G>A p.L442= | Silent (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- GNA11 | c.687C>T p.L229= | Silent (SNP) | VAF 51/216 reads (24%) | catalogued as rs199749164; called by muse, mutect2, varscan2
- MS4A3 | c.276G>A p.P92= | Silent (SNP) | VAF 32/160 reads (20%) | catalogued as rs376718907; called by muse, mutect2, varscan2
- PLA2G3 | c.436C>A p.R146= | Silent (SNP) | VAF 134/442 reads (30%) | catalogued as rs201767666; called by muse, varscan2
- PTPRCAP | c.280C>A p.R94= | Silent (SNP) | VAF 58/262 reads (22%) | catalogued as COSV57047284; called by muse, mutect2, varscan2
- SON | c.1659G>T p.V553= | Silent (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- SRCAP | c.8502G>A p.G2834= | Silent (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- TMEM123 | c.495T>C p.D165= | Silent (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- TRPV1 | c.1938C>T p.G646= | Silent (SNP) | VAF 130/571 reads (23%) | catalogued as rs569486186, COSV51517048; called by muse, mutect2, varscan2
- XYLT1 | c.2385C>T p.Y795= | Silent (SNP) | VAF 86/342 reads (25%) | catalogued as rs139558627; called by muse, mutect2, varscan2
- ZNF746 | c.808C>T p.L270= | Silent (SNP) | VAF 103/437 reads (24%) | called by muse, mutect2, varscan2
- ACSM1 | c.*3G>A | 3'UTR (SNP) | VAF 32/134 reads (24%) | catalogued as rs756257037, COSV99532991; called by muse, mutect2, varscan2
- BAX | c.370-487A>C | Intron (SNP) | VAF 27/118 reads (23%) | called by muse, varscan2
- CCDC78 | c.60+50_60+57del | Intron (DEL) | VAF 74/315 reads (23%) | called by pindel, varscan2*
- CFAP410 | c.78-679C>T | Intron (SNP) | VAF 66/216 reads (31%) | catalogued as rs1359989439; called by muse, mutect2, varscan2
- CTDSPL | c.*1018G>C | 3'UTR (SNP) | VAF 48/118 reads (41%) | called by muse, mutect2, varscan2
- EIF2B5 | c.195+46G>A | Intron (SNP) | VAF 73/271 reads (27%) | catalogued as rs762650029; called by muse, mutect2, varscan2
- FOXP2 | c.*3586G>C | 3'UTR (SNP) | VAF 9/35 reads (26%) | catalogued as rs1034236579; called by muse, mutect2, varscan2
- ICOSLG | c.898+274C>T | Intron (SNP) | VAF 72/138 reads (52%) | catalogued as rs1368906008; called by muse, mutect2, varscan2
- LAYN | c.565+1605C>T | Intron (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- LGALS8 | c.549+254del | Intron (DEL) | VAF 32/134 reads (24%) | called by mutect2, pindel, varscan2
- PDZK1P1 | n.2368C>G | RNA (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- RAB18 | c.*2663A>C | 3'UTR (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- ZNF74 | c.121-996T>A | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
